Somatic mutation profile of tumor specimen 1105220 (aliquot 7316UP-2310-1105220) from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105220: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7935ed2-2b94-42f5-a07b-0385ff9d6589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105210 (Blood Derived Normal), aliquot 7316UP-1848-1105210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb024dbe-2523-4385-8cf2-36f398cf3539

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs970741080, COSV59759638; called by muse, mutect2
- OR52N5 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766003251, COSV57699403; called by muse, mutect2
- SHOX | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs758706054, COSV61860840; called by muse, mutect2
- TTLL7 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1191689608, COSV53081769; called by muse, mutect2
- CHAT | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2
- FOXB2 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 13/436 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- FRAS1 | c.6892A>G p.T2298A | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- H2BC11 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2
- HOXA1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- NBEAL1 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- RPL5 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 17/284 reads (6%) | called by muse, mutect2
- SOS2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- SRSF4 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 29/531 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- TSC22D2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- CFAP20DC | c.1242G>A p.Q414= (on ENST00000482387 / NM_001351530.2; = p.Q289= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2, varscan2
- EHHADH | c.1809T>C p.Y603= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- FREM1 | c.4113T>G p.L1371= | Silent (SNP) | VAF 10/153 reads (7%) | catalogued as rs1284219939; called by muse, mutect2
- GPR156 | c.1443T>C p.D481= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- NDRG1 | c.705C>T p.R235= | Silent (SNP) | VAF 26/475 reads (5%) | catalogued as rs528436514; called by muse, mutect2
- PCDHA2 | c.1527G>A p.S509= | Silent (SNP) | VAF 40/718 reads (6%) | catalogued as COSV65370386; called by muse, mutect2
- PCDHA7 | c.1509G>A p.A503= | Silent (SNP) | VAF 44/684 reads (6%) | catalogued as COSV65347773; called by muse, mutect2
- PCDHB9 | c.1629C>T p.S543= | Silent (SNP) | VAF 49/830 reads (6%) | catalogued as rs373422120, COSV53379717; called by muse, mutect2
- SGCE | c.801G>A p.P267= (on ENST00000647096; = p.P231= on NM_003919.3) | Silent (SNP) | VAF 16/311 reads (5%) | catalogued as rs757206832, COSV56018366; ClinVar: likely benign; called by muse, mutect2
- TGFBI | c.1542C>G p.R514= | Silent (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- PCDHA1 | c.2394+15C>T | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as rs782065488, COSV65374043, COSV65377107; called by muse, mutect2
